Gene-level copy-number profile of tumor specimen TCGA-66-2795-01A from TCGA case TCGA-66-2795, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 68.2 years (24,897 days).
Specimen TCGA-66-2795-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.fac2e8e5-11bf-4c90-befb-f61b4b0a3e8f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2795-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/84bf054f-3300-4baf-bd32-1f824ec83924

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 16,029; copy number 2: 32,873; copy number 3: 6,938; copy number 4: 1,504; copy number 5: 1,352; copy number 6: 1,024; copy number 7: 9; copy number 8: 10; copy number 12: 70.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2795-01A-02D-0978-01): tumor purity 0.66, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,465 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–169,396,540, 1,002 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:172,366,540–174,160,165, 41 genes, copy number 6: RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1, TNFSF18, GOT2P2, AL022310.1, TNFSF4, AL645568.2, AL645568.1, PRDX6-AS1, PRDX6, SLC9C2, AL139142.1, AL139142.2, ANKRD45, TEX50, KLHL20, BX248409.1, RN7SKP160, CENPL, Y_RNA, DARS2, GAS5, GAS5-AS1, ZBTB37, SERPINC1, RNA5SP67, RC3H1, RNA5SP68, RC3H1-IT1, LINC02776, RPL30P1, RABGAP1L-DT.
- chr1:174,367,105–174,449,545, 2 genes, copy number 6: AL022400.1, GPR52.
- chr2:44,361,947–56,750,563, 183 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:58,427,799–59,063,766, 1 gene, copy number 6 (within-gene range 4–8): LINC01122.
- chr2:59,014,354–63,046,487, 80 genes, copy number 8–12 (within-gene range 4–12) (broad region; genes not listed).
- chr3:145,523,538–198,222,513, 933 genes, copy number 6–7 (broad region; genes not listed).
- chr5:6,289,857–7,906,025, 35 genes, copy number 5: HMGB3P3, LINC02145, MED10, AC093307.1, UBE2QL1, AC027334.1, LINC01018, NSUN2, SRD5A1, LINC02102, TENT4A, LINC02236, AC122710.2, MIR4278, LINC02196, RN7SKP79, AC122710.1, RNA5SP176, AC025756.1, AC091889.1, Metazoa_SRP, AC091951.4, AC091951.2, AC091951.3, AC091951.1, AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142, ADCY2, AC093305.1, C5orf49, MTRR, FASTKD3.
- chr6:76,774,972–86,768,932, 117 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:35,080,592–36,279,696, 11 genes, copy number 5: AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3, MTCYBP19, MTND6P19, MTND5P41.
- chr15:43,510,958–43,868,412, 26 genes, copy number 5 (within-gene range 3–5): MAP1A, PPIP5K1, CKMT1B, STRC, RNU6-554P, AC011330.3, CATSPER2, RNU6-610P, AC011330.2, PDIA3P2, AC011330.1, CKMT1A, STRCP1, RNU6-353P, CATSPER2P1, RNU6-354P, PDIA3, ELL3, AC018512.1, SERF2, MIR1282, SERINC4, HYPK, MFAP1, WDR76, Y_RNA.
- chr15:43,875,849–43,876,244, 1 gene, copy number 5: PIN4P1.
- chr19:33,386,950–33,521,791, 1 gene, copy number 6 (within-gene range 4–6): PEPD.
- chr19:58,362,583–58,605,223, 32 genes, copy number 6: AC012313.6, RNA5SP473, ZNF837, RPS5, MIR4754, RNF225, LINC02560, ZNF584, AC012313.1, AC012313.4, AC012313.5, ZNF132, AC012313.8, ZNF324B, ZNF324, ZNF446, AC012313.7, SLC27A5, RNU6-1337P, RN7SL693P, AC012313.9, ZBTB45, RN7SL525P, TRIM28, MIR6807, CHMP2A, UBE2M, MZF1-AS1, MZF1, CENPBD1P1, AC016629.3, AC016629.1.

Autosomal genes at a single copy (total copy number 1): 13,622. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
